Somatic mutation profile of tumor specimen TCGA-GR-A4D4-01A (aliquot TCGA-GR-A4D4-01A-11D-A31X-10) from TCGA case TCGA-GR-A4D4, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-GR-A4D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80b6fcfd-36b9-47eb-a5e6-be00efc385e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GR-A4D4-10A (Blood Derived Normal), aliquot TCGA-GR-A4D4-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd4b8afa-b445-480a-aaa2-ca8628e44835

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Intron 3, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399600925, COSV67796793, COSV67802650; called by muse, mutect2, varscan2
- SPOP | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV61653339, COSV61655858; called by muse, mutect2, varscan2
- TP53 | c.994-2A>G p.X332_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); catalogued as rs867389695, CS159286, COSV52692098, COSV52692518, COSV53122371; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AGA | c.806+2T>C p.X269_splice | Splice Site (SNP) | VAF 52/187 reads (28%) | catalogued as COSV99219638; called by muse, mutect2, varscan2
- AMOTL1 | c.2645G>A p.S882N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100504607; called by muse, mutect2, varscan2
- ANKRD10 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57444450, COSV99941216; called by muse, mutect2, varscan2
- ANKRD46 | c.75T>A p.F25L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100170174; called by muse, mutect2, varscan2
- AP002748.5 | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100568084, COSV59150588; called by muse, mutect2, varscan2
- ARID1A | c.4379G>C p.G1460A | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV100252621, COSV61389619; called by muse, mutect2, varscan2
- ASPM | c.8629A>C p.K2877Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.9); catalogued as COSV99660832; called by muse, mutect2, varscan2
- ATG4C | c.1069A>C p.I357L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV100508446; called by muse, mutect2, varscan2
- ATM | c.7742G>C p.S2581T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53777869, COSV99590828; called by muse, mutect2, varscan2
- BEST1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750102662, CM113166, COSV100077299; called by muse, mutect2, varscan2
- CADM3 | c.708G>C p.M236I (on ENST00000368125 / NM_001127173.3; = p.M270I on NM_021189.5) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100930383; called by muse, mutect2, varscan2
- CENPJ | c.2330T>C p.V777A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs755714584, COSV101121553; called by muse, mutect2, varscan2
- CEP128 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99383506; called by muse, mutect2, varscan2
- CHTF18 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99135908; called by muse, mutect2, varscan2
- CREBBP | c.4447A>T p.I1483F | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52117349; called by muse, mutect2, varscan2
- CS | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV100673279; called by muse, varscan2
- CS | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100673281; called by muse, varscan2
- DDX46 | c.1113T>G p.I371M | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100844909; called by muse, varscan2
- DGKZ | c.2384T>G p.L795R (on ENST00000454345 / NM_001105540.2; = p.L607R on NM_003646.4) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100551778; called by muse, mutect2, varscan2
- DYNC2H1 | c.8048G>C p.R2683T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100519213; called by muse, mutect2, varscan2
- DYRK1A | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100118138; called by muse, mutect2, varscan2
- ENC1 | c.1408A>G p.N470D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100188189; called by muse, mutect2, varscan2
- ERICH1 | c.593A>C p.E198A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100032778; called by muse, mutect2, varscan2
- FARSB | c.437T>A p.L146* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99918165, COSV99918538; called by muse, mutect2, varscan2
- FAS | c.568+2T>A p.X190_splice | Splice Site (SNP) | VAF 32/87 reads (37%) | catalogued as COSV100570854; called by muse, mutect2, varscan2
- FKRP | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100586713; called by muse, mutect2, varscan2
- FOXA1 | c.844A>C p.S282R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99163617; called by muse, mutect2
- H1-2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100642312; called by muse, mutect2, varscan2
- HMX3 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100774156; called by muse, mutect2, varscan2
- KALRN | c.5906G>A p.R1969Q (on ENST00000360013 / NM_001024660.4; = p.R272Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs186931113, COSV99362464; called by muse, mutect2, varscan2
- KCTD20 | c.1184A>C p.H395P | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.006); catalogued as COSV99536154; called by muse, mutect2, varscan2
- LPIN1 | c.2156T>A p.F719Y | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99877943; called by muse, mutect2, varscan2
- LRP8 | c.291C>G p.H97Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100036761; called by muse, mutect2, varscan2
- MED13L | c.5915T>G p.F1972C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929596; called by muse, mutect2, varscan2
- MERTK | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); catalogued as rs376885459; called by muse, varscan2
- MIGA2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs768958718, COSV99477764; called by muse, mutect2, varscan2
- NADK2 | c.372T>G p.H124Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.995); catalogued as COSV99237694; called by muse, varscan2
- NME8 | c.653C>G p.T218R | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99553629; called by muse, mutect2, varscan2
- OBSCN | c.23086C>T p.R7696W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs541725106, COSV63001241; called by muse, mutect2, varscan2
- PLXNA1 | c.2382T>G p.F794L | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99303743; called by muse, mutect2, varscan2
- PODNL1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1472444383, COSV99582977; called by muse, mutect2, varscan2
- POU2F2 | c.715A>G p.T239A (on ENST00000526816 / NM_001207025.3; = p.T223A on NM_002698.5) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60759489, COSV60761129; called by muse, mutect2, varscan2
- PPP1R18 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV51295857, COSV99223809; called by muse, mutect2
- PTCH1 | c.1164C>G p.N388K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100109417, COSV59493086; called by muse, mutect2, varscan2
- PTPRA | c.1619T>G p.L540* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99400339; called by muse, mutect2, varscan2
- RAP1GAP | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.121); catalogued as rs759223775, COSV99265602; called by muse, mutect2, varscan2
- RBBP6 | c.201T>A p.N67K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100154781; called by muse, mutect2, varscan2
- RYR1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100616464; called by muse, mutect2, varscan2
- SGPP1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV55976338, COSV99905935; called by muse, mutect2, varscan2
- SLC7A2 | c.1042G>A p.A348T (on ENST00000494857 / NM_001370338.1; = p.A388T on NM_003046.6) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139867348; called by muse, mutect2, varscan2
- SNX4 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99305173; called by muse, mutect2
- SPHKAP | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100764294; called by muse, mutect2, varscan2
- STAB2 | c.2795G>A p.G932D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186166; called by muse, mutect2, varscan2
- TEK | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs561507573, COSV101193497; called by muse, mutect2, varscan2
- TENM2 | c.4349C>T p.A1450V (on ENST00000518659 / NM_001122679.2; = p.A1211V on NM_001080428.3) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754822894, COSV69129432; called by muse, mutect2, varscan2
- TEX2 | c.1544T>A p.F515Y | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99367289; called by muse, varscan2
- TPR | c.4468T>A p.S1490T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824139; called by muse, mutect2, varscan2
- TUBB | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100013428; called by muse, mutect2, varscan2
- UBR4 | c.2756C>G p.S919C | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100921382; called by muse, mutect2, varscan2
- ZNF768 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.141); catalogued as COSV99411614; called by muse, mutect2, varscan2
- ZP4 | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100850736; called by muse, mutect2, varscan2
- CHD8 | c.1752dup p.Y585Ifs*12 (on ENST00000646647 / NM_001170629.2; = p.Y306Ifs*12 on NM_020920.4) | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | called by mutect2, varscan2
- ZMYND15 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2
- ABCC9 | c.3018G>A p.S1006= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1030642418, COSV53969285; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACCS | c.333C>T p.D111= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99772924; called by muse, mutect2, varscan2
- ART5 | c.615C>T p.C205= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100731688; called by muse, mutect2, varscan2
- CACNG5 | c.744C>T p.S248= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs773065064, COSV99400725; called by muse, mutect2, varscan2
- CCAR2 | c.1182T>A p.I394= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100414822; called by muse, mutect2, varscan2
- CIART | c.405C>T p.D135= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99290376; called by muse, mutect2, varscan2
- COL4A3 | c.4410G>A p.G1470= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs899375646, COSV101170453; called by muse, mutect2, varscan2
- FBXO34 | c.510T>G p.V170= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV100572089; called by muse, mutect2, varscan2
- FNTA | c.1122A>T p.P374= | Silent (SNP) | VAF 93/328 reads (28%) | catalogued as COSV56489191; called by muse, mutect2, varscan2
- FPGT | c.504C>T p.P168= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV100907137; called by muse, mutect2, varscan2
- IGHV1-24 | c.114G>A p.K38= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs201749828; called by muse, mutect2, varscan2
- MTHFD1 | c.2574G>A p.G858= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV99387139; called by muse, mutect2, varscan2
- OCIAD1 | c.69T>A p.P23= | Silent (SNP) | VAF 75/290 reads (26%) | catalogued as COSV99971234; called by muse, varscan2
- RNF214 | c.444T>C p.N148= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100326844; called by muse, mutect2, varscan2
- STRBP | c.603T>C p.S201= | Silent (SNP) | VAF 89/301 reads (30%) | catalogued as rs1283037593, COSV100724282; called by muse, mutect2, varscan2
- TEX2 | c.1461C>A p.L487= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as COSV99367292; called by muse, varscan2
- UBR5 | c.3486T>A p.G1162= | Silent (SNP) | VAF 76/250 reads (30%) | catalogued as COSV99641739; called by muse, mutect2, varscan2
- GSPT1 | c.-63+516C>G | Intron (SNP) | VAF 20/93 reads (22%) | catalogued as COSV101341755; called by muse, mutect2, varscan2
- RBM44 | c.-98-2176_-98-2171delinsG | Intron (DEL) | VAF 68/343 reads (20%) | called by pindel, varscan2*
- TBCE | c.372-3514T>C | Intron (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100783186; called by muse, mutect2, varscan2
